MMRF case MMRF_2329 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/23937dd9-b307-45fa-8d6f-87451ee91993

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.1 years (26,324 days); ISS stage: III; Days to last known disease status: 787 days (2.2 years); Days to last follow up: 787 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 358 days; Days to treatment end: 501 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 502 days (1.4 years); Days to treatment end: 724 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 102 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.48 mg/dL; Immunoglobulin G 3.36 g/L; Immunoglobulin A 34.5 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 6.53 µg/mL; Lactate Dehydrogenase 1.62 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 9.3 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.8 mmol/L; Albumin 41 g/L; Total Protein 9.6 g/dL; Glucose 7.21 mmol/L.
- Day 80 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 4.2 g/L; Immunoglobulin A 3.08 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 7.26 mmol/L.
- Day 162 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.46 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 47 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 7.26 mmol/L.
- Day 269 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 3.05 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 7.92 mmol/L.
- Day 358 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 3.08 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 9.24 mmol/L.
- Day 428 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 58.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.82 mmol/L.
- Day 542 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 7.71 g/L; Immunoglobulin A 2.57 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 7.54 mmol/L.
- Day 633 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 8.84 g/L; Immunoglobulin A 2.25 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 9.41 mmol/L.
- Day 709 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 2.55 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 13.2 mmol/L.
- Day 787 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 2.72 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 9.85 mmol/L.

Other clinical attributes
- Day -6: Weight: 87 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2329_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2329_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
